BEATAML1.0 case 2680 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/24ad29e8-fe35-4606-aca0-8af9ba00629b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Acute myeloid leukemia with inv(3)(q21q26.2) or t(3;3)(q21;q26.2), RPN1-EVI1: ICD-O-3 morphology code: 9869/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,590 days); Progression or recurrence: no.

Biospecimens (3 samples)
- Sample BA3373D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA3373R: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
- Sample BA3393D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
